Gene-level copy-number profile of tumor specimen TCGA-24-2019-01A from TCGA case TCGA-24-2019, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.6 years (17,009 days).
Specimen TCGA-24-2019-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.61a93ace-fc9c-44c5-a6fd-341bbc767f25.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2019-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/86a137eb-93d5-43fa-b498-eb7fe5c298a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 2,580; copy number 2: 23,358; copy number 3: 16,906; copy number 4: 12,292; copy number 5: 3,166; copy number 6: 708; copy number 7: 178; copy number 8: 10; copy number 9: 126; copy number 10: 12; copy number 11: 136; copy number 13: 121; copy number 14: 85; copy number 15: 1; copy number 17: 58; copy number 22: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2019-01A-02D-0663-01): tumor purity 0.85, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:25,279,529–25,729,294, 18 genes: AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2, AL022329.1, GRK3, AL022329.2, YES1P1, RNA5SP494.
- chr22:25,756,318–25,756,669, 1 gene: AL022329.3.
- chr22:29,327,680–29,423,179, 1 gene (within-gene range 0–2): AP1B1.
- chr22:29,387,909–29,435,005, 3 genes: AC002059.3, AC000041.1, RFPL4AP6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,595 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–81,666,728, 1,372 genes, copy number 5–6 (broad region; genes not listed).
- chr2:112,541,915–113,756,693, 53 genes, copy number 5 (within-gene range 3–5): POLR1B, Y_RNA, CHCHD5, AC012442.2, AC012442.1, AC079922.1, AC079922.2, SLC20A1, NT5DC4, CKAP2L, IL1A, AC079753.2, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782.
- chr3:52,833,121–53,865,794, 22 genes, copy number 5 (within-gene range 4–5): STIMATE-MUSTN1, STIMATE, MIR8064, AC099667.1, SFMBT1, AC096887.1, AC096887.2, SERBP1P3, RFT1, PRKCD, AC097015.1, TKT, DCP1A, Y_RNA, CACNA1D, SNORD38C, AC112218.1, AC092035.1, SNORD63, AC012467.1, CHDH, IL17RB.
- chr4:5,897,373–6,308,636, 10 genes, copy number 5 (within-gene range 3–5): C4orf50, MIR378D1, JAKMIP1, AC092442.1, AC113615.2, LINC02495, AC113615.1, AC116317.2, WFS1, AC116317.1.
- chr4:133,871,246–155,385,492, 320 genes, copy number 5 (broad region; genes not listed).
- chr7:15,200,317–37,449,249, 401 genes, copy number 7–17 (broad region; genes not listed).
- chr7:107,923,799–108,995,029, 15 genes, copy number 6 (within-gene range 4–6): LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr7:157,539,056–158,587,823, 1 gene, copy number 5 (within-gene range 4–5): PTPRN2.
- chr7:157,987,169–159,233,377, 16 genes, copy number 5: AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:52,622,458–56,993,867, 77 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:100,683,488–101,669,726, 35 genes, copy number 7: RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1.
- chr8:101,686,547–101,872,549, 3 genes, copy number 7: AP000426.1, AP001329.1, PDCL3P2.
- chr10:79,661,394–79,826,594, 1 gene, copy number 5 (within-gene range 4–5): NUTM2B-AS1.
- chr10:79,703,227–80,717,068, 40 genes, copy number 5: NUTM2B, AL135925.1, NUTM2E, NPAP1P2, CTSLP6, PGGT1BP2, AL512662.1, BMS1P21, MBL1P, SFTPD, SFTPD-AS1, ZNRF2P3, DPY19L2P5, AL356095.1, C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9, ANXA11, LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14, AC021028.1, SH2D4B, LINC02655, RPS7P9.
- chr12:66,767–6,538,374, 165 genes, copy number 5–7 (broad region; genes not listed).
- chr12:49,866,896–56,874,268, 369 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:111,034,165–133,214,832, 616 genes, copy number 5–6 (broad region; genes not listed).
- chr14:20,983,155–21,841,774, 62 genes, copy number 13 (broad region; genes not listed).
- chr14:81,221,218–82,796,221, 18 genes, copy number 10–14: AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1, Metazoa_SRP, LINC02301, ENSAP2, AL355095.1.
- chr14:84,739,942–88,326,907, 34 genes, copy number 5–15 (within-gene range 2–15): RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309, LINC01148, AL358292.1, AL352955.1, AL157688.1, LINC02296, AL135746.1, LINC02330, AL359237.1, AL136501.1, GALC, SHLD2P2, RNU6-835P, GPR65, AL157955.1, LINC01147, LINC01146, AL133279.2, AL133279.3, AL133279.1, KCNK10.
- chr14:91,060,333–91,225,632, 1 gene, copy number 5 (within-gene range 2–5): DGLUCY.
- chr14:91,126,425–91,575,271, 11 genes, copy number 5: SNORA11B, GPR68, AL135818.1, AL135818.2, AL135818.3, CCDC88C, AL133153.2, AL133153.1, PPP4R3A, AL133373.2, AL133373.3.
- chr14:102,777,449–105,601,728, 119 genes, copy number 6–14 (within-gene range 2–14) (broad region; genes not listed).
- chr18:976,589–1,408,344, 7 genes, copy number 6 (within-gene range 2–6): AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr18:1,927,727–1,929,094, 1 gene, copy number 8: AIDAP3.
- chr18:11,366,913–11,885,685, 20 genes, copy number 6 (within-gene range 3–6): AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2.
- chr19:15,821,796–15,836,328, 5 genes, copy number 5: ZNF861P, AC004510.2, LINC01764, UCA1, AC004510.1.
- chr19:27,638,483–29,824,312, 51 genes, copy number 22: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1.
- chr20:23,980,585–39,039,723, 374 genes, copy number 5–6 (broad region; genes not listed).
- chr20:61,252,261–61,940,617, 1 gene, copy number 6 (within-gene range 4–6): CDH4.
- chr20:61,369,879–64,313,132, 142 genes, copy number 6 (broad region; genes not listed).
- chr21:10,328,411–18,935,859, 128 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:29,436,534–31,280,080, 87 genes, copy number 7 (within-gene range 0–7) (broad region; genes not listed).
- chr22:32,205,115–32,278,382, 1 gene, copy number 6 (within-gene range 2–6): SLC5A4-AS1.
- chr22:32,269,381–32,498,829, 15 genes, copy number 6: CPSF1P1, AL008723.2, AL021937.3, RFPL3, IGLCOR22-2, RFPL3S, AL021937.6, AL021937.5, AL021937.1, IGLVIVOR22-2, AL021937.4, AL021937.2, RTCB, BPIFC, FBXO7.
- chr22:32,583,300–32,635,198, 2 genes, copy number 6: SYN3-AS1, RNA5SP497.

Autosomal genes at a single copy (total copy number 1): 2,580. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
